Somatic mutation profile of tumor specimen 0DWM1N from CCDI case PBCPCG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.5 years (4,196 days).
Specimen 0DWM1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 029dacc3-28c3-4556-8a92-1bb9a3e84b11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfc4463c-3970-4ddb-a8e3-d86d4d93826d

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf226 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 56/542 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1252419120, COSV63396085; called by muse, mutect2
- TCN1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 139/1310 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77116206, COSV57253579; called by muse, mutect2, varscan2
- CD248 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- KMT2A | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCA | c.79+67G>A | Intron (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 5/73 reads (7%) | catalogued as COSV55814242; called by muse, mutect2
- SHANK3 | chr22:50731341 T>G | 3'Flank (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2
